Somatic mutation profile of tumor specimen ALCH-B34G-TTP1-C (aliquot ALCH-B34G-TTP1-C-1-0-D-A799-36) from ALCHEMIST case ALCH-B34G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,224 days).
Specimen ALCH-B34G-TTP1-C: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 995b46b9-41b8-4701-b7e1-9e0847db8d39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34G-NB1-A (Blood Derived Normal), aliquot ALCH-B34G-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09ab807c-d6dd-4ad6-9c49-3c2e01f3ab9a

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, 3'UTR 2, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MFN2 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 50/628 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs119103263, CM060342; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 22/250 reads (9%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2
- CLU | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs761369634, COSV57066672; called by muse, mutect2, varscan2
- ERN2 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs769545035, COSV56834803; called by muse, mutect2
- HMGXB3 | c.3659A>G p.D1220G (on ENST00000613459; = p.D974G on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1203014409; called by muse, mutect2
- LRP1 | c.3863A>G p.D1288G | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs201057591; called by muse, mutect2
- P3H3 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782784082; called by muse, mutect2
- SBDS | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747312896, COSV55888262; called by muse, mutect2, varscan2
- SMTNL2 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs1478793057, COSV58807225; called by muse, mutect2
- SPTB | c.5414C>T p.T1805M | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs142051792; called by muse, mutect2
- SPTBN4 | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1264768674; called by muse, mutect2
- WDR3 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62522549; called by muse, mutect2
- ADAM23 | c.1967T>C p.F656S | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ADAMTS5 | c.1488G>C p.Q496H | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ALPK1 | c.3518del p.D1173Vfs*10 | Frame Shift Del (DEL) | VAF 14/152 reads (9%) | called by mutect2, pindel, varscan2
- FGD5 | c.3155-2A>T p.X1052_splice | Splice Site (SNP) | VAF 16/280 reads (6%) | called by muse, mutect2
- HIVEP2 | c.1682G>A p.R561K | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IL17RD | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2
- MET | c.2888-17_2888-2del p.X963_splice | Splice Site (DEL) | VAF 42/364 reads (12%) | called by mutect2, pindel, varscan2
- MYPN | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- PGBD4 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2
- PIEZO2 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2
- PRG4 | c.22A>T p.I8F | Missense Mutation (SNP) | VAF 18/465 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- RBM10 | c.2370del p.H791Tfs*11 | Frame Shift Del (DEL) | VAF 35/293 reads (12%) | called by mutect2, pindel, varscan2
- SENP5 | c.1619G>T p.R540I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- TMEM167A | c.179G>C p.C60S | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- UBE4A | c.1791A>T p.Q597H (on ENST00000252108 / NM_001204077.2; = p.Q604H on NM_004788.4) | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.344); called by muse, mutect2
- ZZZ3 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.135); called by muse, mutect2
- CPO | c.1053G>T p.S351= | Silent (SNP) | VAF 38/445 reads (9%) | catalogued as COSV99786462; called by muse, mutect2
- DYNC1H1 | c.6438G>A p.V2146= | Silent (SNP) | VAF 13/278 reads (5%) | called by muse, mutect2
- GALNT7 | c.192C>T p.D64= | Silent (SNP) | VAF 22/289 reads (8%) | called by muse, mutect2
- PDGFRA | c.864C>T p.Y288= | Silent (SNP) | VAF 18/256 reads (7%) | catalogued as rs769092243, COSV57268358; ClinVar: likely benign; called by muse, mutect2
- RABAC1 | c.279C>A p.S93= | Silent (SNP) | VAF 13/319 reads (4%) | called by muse, mutect2
- SEMA6A | c.804C>G p.V268= | Silent (SNP) | VAF 32/315 reads (10%) | called by muse, mutect2
- SPNS2 | c.834C>T p.L278= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as rs776727351; called by muse, mutect2
- TECTA | c.5604C>T p.I1868= | Silent (SNP) | VAF 40/398 reads (10%) | catalogued as COSV50802386; called by muse, mutect2
- TNS3 | c.2310G>A p.G770= | Silent (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- ATP2B2 | c.*153G>A | 3'UTR (SNP) | VAF 12/250 reads (5%) | catalogued as rs1206866742, COSV59488068, COSV59502274; called by muse, mutect2
- PPARA | c.711+13G>A | Intron (SNP) | VAF 24/364 reads (7%) | catalogued as rs572800251; called by muse, mutect2
- UMPS | c.*4334G>A | 3'UTR (SNP) | VAF 14/379 reads (4%) | catalogued as rs1020340812; called by muse, mutect2
